Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0YI, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0YI-01A (Primary Tumor).

[page 1 of 3]
Chief of Pathology

Phone

Fax

Specimen:

Received:

Spec Type: SURGICAL P

Status:

Subm Dr:

PREOPERATIVE DIAGNOSIS

RIGHT BREAST CANCER INVASIVE

OPERATION PERFORMED

DATE:

DOCTOR(S):

PROCEDURE: MASTECTOMY PARTIAL/LUMPECTOMY/EXCISION SENTINEL NODE

TISSUE REMOVED

- A. RT BREAST
- B. RT SENTINEL NODE #1
- C. RT NON SENTINEL NODE
- D. RT SENTINEL NODE #2
- E. RT BREAST ADDITIONAL POST INK NEW MARGIN

GROSS DESCRIPTION

PART A RECEIVED LABELED [REDACTED] RIGHT BREAST 10 O'CLOCK LONG EQUALS LATERAL SHORT EQUALS SUPERIOR, IS AN OVOID PORTION OF YELLOW FATTY TISSUE MEASURING 9.5 X 6.3 X 4.0 CM. THE SPECIMEN IS ORIENTED BY TWO SUTURES AND BLUE DYE IS NOTED WITHIN THE SPECIMEN. SUPERFICIALLY ON THE LATERAL ONE-HALF, THERE IS A SKIN ELLIPSE MEASURING 4.2 X 0.8 CM. TWO NEEDLE LOCALIZATION WIRES ENTER THE INFERIOR LATERAL ASPECT OF THE SPECIMEN. SECTIONING REVEALS THE MAJORITY OF THE SPECIMEN TO CONSIST OF BLAND YELLOW FATTY TISSUE WITH FINE FIBROUS BANDS. IN THE MIDPORTION OF THE SPECIMEN, THERE IS A PINK-TAN GRITTY AREA. THIS IS IN THE MEDIAL ONE-HALF, AND LATERAL TO THIS, THERE IS DENSE PINK-TAN FIBROUS TISSUE. THE FIRM AREA MEASURES 1.7 X 1.4 X 2.0 CM IN GREATEST DIMENSIONS. THERE IS A SECOND FIRM AREA IMMEDIATELY INFERIOR TO THIS AREA WHICH BY PALPATION MEASURES 0.7 CM IN GREATEST DIMENSION. THIS APPROACHES THE INFERIOR MARGIN BY 0.3 CM. THE LARGER LESION IS 1 CM FROM THE CLOSEST MARGIN, WHICH IS SUPERFICIAL AND DEEP. SECTIONS ARE SUBMITTED AS FOLLOWS: A1--PERPENDICULAR MEDIAL MARGIN, A2--PERPENDICULAR LATERAL MARGIN, A3--CENTRAL TUMOR (MIRROR IMAGE TO PROTOCOL). A4 THROUGH A8--TISSUE SURROUNDING A3 AS FOLLOWS: DEEP MARGIN, INFERIOR MARGIN TO INCLUDE SEPARATE PALPABLE NODULE, A6--SUPERFICIAL INFERIOR ASPECT, A7--SUPERFICIAL MARGIN, A8--SUPERIOR MARGIN. A9 AND 10--FULL CROSS-SECTION OF LESION TO INCLUDE THE DEEP AND SUPERFICIAL MARGINS, RESPECTIVELY; A11--LATERAL ASPECT OF LESION TO INCLUDE SUPERFICIAL MARGIN (MIRROR IMAGE TO PROTOCOL).

PART B RECEIVED FRESH LABELED [REDACTED] RIGHT SENTINEL NODE #1 HOT AND BLUE, ARE TWO PORTIONS OF YELLOW-PINK FATTY TISSUE MEASURING 1.7 X 1 X 0.5 CM AND 1.7 X 1.5 X 0.8 CM. IN THE SMALLER PORTION, THERE IS A 0.6-CM GROSSLY UNREMARKABLE LYMPH NODE. THE LARGER PORTION CONSISTS OF FATTY TISSUE WITH FOCAL BLUE DYE. BLUE DYE IS ALSO NOTED WITHIN THE NODE. THE SPECIMEN IS SUBMITTED ENTIRELY LABELED B.

[page 2 of 3]
Phone
Fax

Patient:

(Continued)

Specimen:

Received:

Status:

Spec Type: SURGICAL P
(Continued)

Subm Dr:

GROSS DESCRIPTION

PART C RECEIVED FRESH LABELED RIGHT NONSENTINEL LYMPH NODE, IS AN OVOID PORTION OF PINK-TAN TISSUE MEASURING 1.8 X 1 X 1 CM. SECTIONING REVEALS IT TO BE A GROSSLY UNREMARKABLE LYMPH NODE. A PORTION IS SUBMITTED PER PROTOCOL. THE REMAINDER IS SUBMITTED LABELED C.

PART D RECEIVED FRESH LABELED SENTINEL NODE #2 HOT, IS AN IRREGULAR PORTION OF YELLOW-RED FATTY TISSUE MEASURING 2.5 X 1.5 X 1.0 CM. NO DISTINCT NODAL TISSUE IS IDENTIFIED. THE SPECIMEN IS ENTIRELY SUBMITTED LABELED D.

PART E RECEIVED LABELED RIGHT BREAST ADDITIONAL POSTERIOR INK AT NEW MARGIN, IS AN OVOID PORTION OF YELLOW FATTY TISSUE MEASURING 6 X 4.8 X 0.8 CM. THE SIDE OF THE SPECIMEN WHICH DEMONSTRATES THE INK IS MARKED WITH BLUE INK WITH A PERIMETER OF BLACK INK. THIS IS SECTIONED AND SUBMITTED ENTIRELY LABELED E1 THROUGH 9.

PATH PROCEDURE

PROCEDURES:

88305, 88307/4, IMMUNOPEROXIDAS/2, A BLK/11, BBX X6, C BLK, DBX X6, E BLK/9

FINAL DIAGNOSIS

PART A RIGHT BREAST, PARTIAL MASTECTOMY:

1. MODERATELY DIFFERENTIATED IN SITU AND INFILTRATING CARCINOMA WITH MIXED DUCTAL AND LOBULAR DIFFERENTIATION, PREDOMINANTLY LOBULAR, NUCLEAR GRADE I WITH LOW MITOTIC INDEX, WITH AN IN SITU COMPONENT OF APPROXIMATELY 20% OF SOLID AND CRIBRIFORM TYPE.
2. TWO (2) TUMOR NODULES ARE PRESENT MEASURING 1.7 AND 0.5 CM IN GREATEST DIMENSION. ALL MARGINS OF RESECTION ARE FREE OF NEOPLASM BY A DISTANCE OF 5 MM OR GREATER.
3. LYMPHATIC INVASION IS NOT IDENTIFIED.
4. FIBROCYSTIC DISEASE.
5. BIOPSY SITE CHANGE WITH ORGANIZING FAT NECROSIS AND REACTIVE FIBROSIS.

PART B RIGHT SENTINEL NODE #1, BIOPSY: LYMPH NODE (1) WITH A MINUTE FOCUS OF ISOLATED TUMOR CELLS WHICH IS ONLY VISIBLE ON CYTOKERATIN STAIN AND NOT ON THE ROUTINE STEP SECTIONS. THE FOCUS OF TUMOR CELLS MEASURES APPROXIMATELY 0.05 MM IN GREATEST DIMENSION.

PART C RIGHT NONSENTINEL LYMPH NODE, BIOPSY: LYMPH NODE (1) WITH FATTY INFILTRATION, NEGATIVE FOR TUMOR.

PART D RIGHT SENTINEL NODE #2, BIOPSY: ADIPOSE TISSUE CONTAINING A

[page 3 of 3]
Chief of Pathology

Phone

Fax

Patient:

(Continued)

Specimen:

Received:

Status:

Spec Type: SURGICAL P

Subm Dr:

FINAL DIAGNOSIS

(Continued)

MINUTE CRUSHED LYMPHOID AGGREGATE, NEGATIVE FOR TUMOR BY STEP SECTION AND CYTOKERATIN STAIN.

PART E RIGHT BREAST, ADDITIONAL POSTERIOR MARGIN: LIPOMATOUS BREAST TISSUE WITH NO EVIDENCE OF RESIDUAL NEOPLASM. THE NEW INKED MARGIN IS FREE OF NEOPLASM. FIBROCYSTIC CHANGE WITH DUCT HYPERPLASIA OF THE USUAL TYPE WITH INTRADUCTAL PAPILLOMATOSIS, APOCRINE METAPLASIA AND CYST FORMATION.

CODE

1

Signed

(prelim.)

(signature on file)

Mixed - ductal + lobular

Case is (check):		

Source: NCI Genomic Data Commons file 42dd4eea-b5af-4c8a-ab9d-c540a44de3ec (TCGA-A2-A0YI.CEFD12BB-1AF7-400D-8A84-49650DFDD8A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).